Somatic mutation profile of tumor specimen TCGA-Y8-A8S1-01A (aliquot TCGA-Y8-A8S1-01A-11D-A36X-10) from TCGA case TCGA-Y8-A8S1, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 61.1 years (22,319 days).
Specimen TCGA-Y8-A8S1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ecf5198a-e108-4cca-9372-9cac7c585c6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Y8-A8S1-10A (Blood Derived Normal), aliquot TCGA-Y8-A8S1-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1195259b-8fb8-4741-a94a-5fb7d9489156

The open-access MAF lists 60 somatic variants for this specimen: 48 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 11, Frame Shift Del 3, In Frame Del 2, Nonsense Mutation 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATG2B | c.2766G>C p.M922I | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV63424104; called by muse, mutect2, varscan2
- ATXN2 | c.810T>A p.H270Q (on ENST00000550104; = p.H110Q on NM_002973.4) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV101112619; called by muse, mutect2, varscan2
- B3GALT4 | c.976A>C p.K326Q | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.034); catalogued as COSV101005573; called by muse, mutect2, varscan2
- CRB2 | c.542G>A p.C181Y | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100749552; called by muse, mutect2, varscan2
- DNAH2 | c.2926C>T p.R976C | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199537692, COSV101209068; called by muse, mutect2, varscan2
- DOCK8 | c.5338G>T p.D1780Y | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as COSV101209829; called by muse, mutect2
- DYM | c.479C>G p.T160S | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99492704; called by muse, mutect2, varscan2
- EPHA3 | c.2440C>T p.L814F | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100343535; called by muse, mutect2, varscan2
- GABBR1 | c.1481G>A p.R494H | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs548511243, COSV63540823; called by muse, mutect2, varscan2
- GRM1 | c.1535T>C p.I512T | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as COSV99264587; called by muse, mutect2, varscan2
- HNRNPDL | c.410A>G p.K137R | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as COSV99787017; called by muse, mutect2, varscan2
- IGDCC4 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.095); catalogued as COSV100732732; called by mutect2, varscan2
- KANSL1 | c.1043G>T p.R348L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99294158; called by muse, mutect2, varscan2
- KAZN | c.839T>C p.L280P | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV100747691; called by muse, mutect2, varscan2
- KDF1 | c.158A>G p.H53R | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746153605, COSV100264402; called by muse, mutect2, varscan2
- KDM4A | c.467T>A p.I156N | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100969392; called by muse, mutect2, varscan2
- KLF11 | c.1357A>T p.K453* | Nonsense Mutation (SNP) | VAF 21/135 reads (16%) | catalogued as rs777077418, COSV59940525; called by muse, mutect2, varscan2
- KLF11 | c.1358A>T p.K453M | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762130773, COSV100007671; called by muse, mutect2, varscan2
- MED1 | c.2702A>G p.Q901R | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as COSV100327510; called by muse, mutect2, varscan2
- MUC5B | c.527G>C p.S176T | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.048); catalogued as COSV101500077; called by muse, mutect2, varscan2
- MYH6 | c.2057T>C p.M686T | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV100676349; called by muse, mutect2, varscan2
- NBEA | c.4210C>A p.L1404I | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100077447; called by muse, mutect2
- NCDN | c.761C>G p.P254R | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.467); catalogued as COSV100356977; called by muse, mutect2, varscan2
- NLRP11 | c.2870G>A p.G957D | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100789652; called by muse, mutect2, varscan2
- OR5H14 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV101454343, COSV71193561; called by muse, mutect2, varscan2
- PDS5A | c.1105T>C p.S369P | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.876); catalogued as COSV100337210; called by muse, mutect2, varscan2
- PPFIA2 | c.2003A>G p.Q668R | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100332008; called by muse, mutect2
- PRR12 | c.3008C>T p.S1003F (on ENST00000615927; = p.S1824F on NM_020719.3) | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV101330592; called by muse, mutect2
- RBM33 | c.527T>A p.V176E | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99841022; called by muse, mutect2, varscan2
- SBNO1 | c.380C>T p.T127I (on ENST00000420886; = p.T126I on NM_018183.5) | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV99928838; called by muse, mutect2, varscan2
- SF3A1 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.87); catalogued as rs1160166604, COSV53171154; called by muse, mutect2
- SMC6 | c.1987G>C p.D663H | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100704840, COSV61173889; called by muse, mutect2, varscan2
- STAP2 | c.353A>C p.E118A | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV101653389; called by muse, mutect2
- SV2C | c.1750T>G p.F584V | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); catalogued as COSV100455779; called by muse, mutect2, varscan2
- TAS1R3 | c.335C>G p.P112R | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100229310; called by muse, mutect2, varscan2
- TMEM51 | c.455C>G p.P152R | Missense Mutation (SNP) | VAF 37/302 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV101051490; called by muse, mutect2, varscan2
- TPD52L3 | c.62T>C p.L21P | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1474883857, COSV100095894; called by muse, mutect2, varscan2
- TRIP10 | c.820T>C p.S274P | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100504918; called by muse, mutect2, varscan2
- UBQLN3 | c.523C>A p.P175T | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV100293417, COSV100293425; called by muse, mutect2, varscan2
- UTRN | c.124A>T p.N42Y | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100839665, COSV62329952; called by muse, mutect2, varscan2
- VIRMA | c.5170G>A p.G1724S | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.846); catalogued as rs376333024; called by muse, mutect2, varscan2
- ZKSCAN1 | c.1008G>T p.K336N | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100164121; called by muse, mutect2, varscan2
- H1-5 | c.607_651del p.P203_K217del | In Frame Del (DEL) | VAF 12/157 reads (8%) | called by mutect2, pindel
- PRDM10 | c.964_966+8del p.X322_splice | Splice Site (DEL) | VAF 7/86 reads (8%) | called by mutect2, pindel
- REV1 | c.1823_1831del p.V608_I610del | In Frame Del (DEL) | VAF 15/154 reads (10%) | called by mutect2, pindel
- RPL22 | c.17del p.K6Sfs*4 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | called by mutect2, pindel, varscan2
- SHROOM3 | c.2452del p.S818Pfs*24 | Frame Shift Del (DEL) | VAF 15/139 reads (11%) | called by mutect2, pindel, varscan2
- TMF1 | c.549_552del p.K183Nfs*4 | Frame Shift Del (DEL) | VAF 18/153 reads (12%) | called by mutect2, pindel, varscan2
- APOF | c.648T>C p.D216= | Silent (SNP) | VAF 17/113 reads (15%) | catalogued as COSV100028661; called by muse, mutect2, varscan2
- CELSR3 | c.5604T>A p.L1868= | Silent (SNP) | VAF 19/134 reads (14%) | catalogued as COSV50868851, COSV99372803; called by muse, mutect2, varscan2
- DNAH8 | c.7179C>A p.T2393= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV100543688, COSV100544422; called by muse, mutect2, varscan2
- GIP | c.285G>A p.E95= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100656949, COSV62467282; called by mutect2, varscan2
- IMPACT | c.450G>C p.S150= | Silent (SNP) | VAF 16/123 reads (13%) | catalogued as COSV99408791; called by muse, mutect2, varscan2
- PKHD1 | c.1137C>T p.F379= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV100581598; called by muse, mutect2, varscan2
- STAT6 | c.2388T>C p.P796= | Silent (SNP) | VAF 22/136 reads (16%) | catalogued as COSV100272580; called by muse, mutect2, varscan2
- STMN2 | c.441G>A p.E147= | Silent (SNP) | VAF 16/123 reads (13%) | catalogued as COSV99626193; called by muse, mutect2, varscan2
- TEX15 | c.5757A>G p.R1919= (on ENST00000256246; = p.R2302= on NM_001350162.2) | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as COSV99820852; called by muse, mutect2
- USP45 | c.2235C>T p.G745= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as COSV100569527; called by muse, mutect2, varscan2
- ZNF619 | c.675C>T p.F225= | Silent (SNP) | VAF 18/123 reads (15%) | catalogued as COSV100123088; called by muse, mutect2, varscan2
- YPEL3 | c.-19_-11del | 5'UTR (DEL) | VAF 5/51 reads (10%) | called by mutect2, pindel
